Surgical pathology report (de-identified scan), TCGA case TCGA-26-1440, project TCGA-GBM (Glioblastoma Multiforme), tissue source site University of Florida, specimen TCGA-26-1440-01A (Primary Tumor).

[page 1 of 2]
Case Type: [REDACTED]
Accession #: [REDACTED]
Name: [REDACTED]
MRN: [REDACTED]
Pt. Location: [REDACTED]
Date Received: [REDACTED]
Date of Collection: [REDACTED]
Ref. MD: [REDACTED]

26-1440

SPECIMEN(S) SUBMITTED/ PROCEDURES ORDERED:

A. Tumor (88307) A. Frozen Section Charge (88331) B.
Tumor #2 (88307) C. Tumor #3 (88307)

CLINICAL HISTORY: [REDACTED]

[REDACTED] in his visual field (left eye). The patient reports [REDACTED]. He presents today for a left craniotomy and resection of mass in the left temporal lobe.

GROSS DESCRIPTION: Received the following specimens in the Department of Pathology, labeled with the patient's name and hospital #:

- A. Tumor
- B. Tumor #2
- C. Tumor #3

A. The specimen is received without fixative labeled "tumor" and consists of a 1.2 x 0.3 x 0.2 cm aggregate of pink-tan soft tissue. A representative portion of the tissue is submitted for frozen section. Frozen section diagnosis is "Glioblastoma multiforme" per [REDACTED]

[REDACTED] The frozen tissue is submitted for permanent processing in cassette FSA1. The remaining tissue is entirely submitted in cassette A2.

B. The specimen is received without fixative labeled "tumor #2" and consists of a 2.9 x 2.7 x 0.6 cm aggregate of focally hemorrhagic pink-tan soft tissue. A representative portion of the tissue is submitted to the MTI Tumor Bank for possible future studies. The remaining tissue is entirely submitted in cassette B1 through B4. [REDACTED]

C. The specimen is received without fixative labeled "tumor #3" and consists of a 2.9 x 2.0 x 0.8 cm aggregate of focally hemorrhagic and necrotic red-tan soft tissue. A representative portion of the more viable tissue is submitted to the MBI Tumor Bank for possible future studies. The remaining tissue is entirely submitted in cassette C1 through C3.

DIAGNOSIS:

- A. "Tumor";

[page 2 of 2]
- [REDACTED]
- Glioblastoma multiforme (WHO Grade IV astrocytoma)
- B. "Tumor #2":
Glioblastoma multiforme (WHO Grade IV astrocytoma)
- C. "Tumor #3":
Glioblastoma multiforme (WHO Grade IV astrocytoma)

"I, or my qualified designee, have performed the gross examination and description and I have personally reviewed the gross description and specimen preparations referenced herein, and have personally issued this report."

Resident/Prosector/Pathologist: [REDACTED]

ICD9 Codes: 191.9

Diagnostic/Retrieval Codes: [REDACTED]

Note: Test systems have been developed and their performance characteristics determined by [REDACTED] Some tests have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance is not necessary. These tests are used for clinical purposes and should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] as qualified to perform high complexity clinical laboratory testing.

[REDACTED]

Pathologist

Electronically signed [REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file cc5f8885-ec6e-4ca0-925c-07169fcfad29 (TCGA-26-1440.B392EFBA-D6F2-48E6-BF80-D62CB986F1DD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).